Gene-level copy-number profile of tumor specimen TCGA-L5-A8NU-01A from TCGA case TCGA-L5-A8NU, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-L5-A8NU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.ef526ffe-00c2-4739-a4f9-ad1d3bc95a1e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A8NU-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6eea98e7-c527-4d51-bf13-aa89fb8edee7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 19,545; copy number 2: 39,200; copy number 3: 774; copy number 4: 145; copy number 5: 113; copy number 6: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A8NU-01A-11D-A36I-01): tumor purity 0.24, ploidy 1.8, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 150 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:59,747,277–61,251,459, 1 gene, copy number 5 (within-gene range 1–5): FHIT.
- chr3:60,616,822–63,125,062, 20 genes, copy number 5 (within-gene range 4–5): AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71, U3, PTPRG, Y_RNA, RPL10AP6, RNU2-10P, ID2B, PTPRG-AS1, C3orf14, FEZF2, CADPS, AC012519.1, RN7SL863P, RNU6-139P, AC096915.1, LINC00698.
- chr3:66,003,839–69,593,121, 37 genes, copy number 6: Y_RNA, AC106827.1, SLC25A26, RNU6-787P, RN7SL482P, LRIG1, AC104440.1, RPL21P41, AC098969.2, AC098969.1, AC020655.1, KBTBD8, MIR4272, AC114401.1, SUCLG2, NDUFB4P1, SUCLG2-AS1, TAFA1, COPS8P2, AC107626.1, AC104167.1, AC096922.1, PSMC1P1, TAFA4, RNA5SP135, EOGT, AC109587.1, TMF1, MIR3136, UBA3, ARL6IP5, LMOD3, FRMD4B, RBM43P1, AC099328.1, AC099328.2, AC104445.1.
- chr3:70,751,123–75,785,583, 91 genes, copy number 5 (broad region; genes not listed).
- chr3:75,964,980–75,965,069, 1 gene, copy number 5: Y_RNA.

Autosomal genes at a single copy (total copy number 1): 17,165. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
